Somatic mutation profile of tumor specimen TCGA-BG-A0VW-01A (aliquot TCGA-BG-A0VW-01A-11D-A122-09) from TCGA case TCGA-BG-A0VW, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 77.7 years (28,383 days).
Specimen TCGA-BG-A0VW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3da3d3dd-9968-4d39-a4e4-7ff4fd3e9c3e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A0VW-10A (Blood Derived Normal), aliquot TCGA-BG-A0VW-10A-01D-A122-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa7f4033-4e60-49c2-9f6a-c28c85b75c0f

The open-access MAF lists 510 somatic variants for this specimen: 375 protein-altering or splice-affecting, 129 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 276, Silent 129, Frame Shift Del 60, Nonsense Mutation 18, Frame Shift Ins 9, In Frame Del 5, Splice Site 5, Intron 3, Splice Region 2, RNA 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B4GALNT1 | c.263del p.G88Afs*24 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | catalogued as rs745744124; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BCOR | c.4376A>G p.N1459S (on ENST00000378444 / NM_001123385.2; = p.N1425S on NM_017745.6) | Missense Mutation (SNP) | VAF 51/132 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as rs199538037, COSV60698733; called by muse, mutect2, varscan2
- EARS2 | c.328G>A p.G110S | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201842633, CM123410; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 50/323 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MCPH1 | c.321del p.K107Nfs*39 | Frame Shift Del (DEL) | VAF 42/118 reads (36%) | catalogued as rs759663956; ClinVar: pathogenic; called by mutect2, varscan2
- MTOR | c.5930C>T p.T1977I | Missense Mutation (SNP) | VAF 66/236 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs587777893, COSV63868784, COSV63869673, COSV63869920; ClinVar: pathogenic; called by muse, mutect2
- PIK3R2 | c.1117G>A p.G373R | Missense Mutation (SNP) | VAF 34/101 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587776934, CM126686, COSV55846573; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.276C>G p.D92E | Missense Mutation (SNP) | VAF 95/312 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM033666, COSV64288954, COSV64292660; called by muse, mutect2, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 64/229 reads (28%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.956_959del p.T319Kfs*24 | Frame Shift Del (DEL) | VAF 51/176 reads (29%) | catalogued as rs398123330, COSV64288731; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SETX | c.6407G>A p.R2136H | Missense Mutation (SNP) | VAF 98/271 reads (36%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.887); catalogued as rs121434378, CM041510, COSV56388997; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP63 | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs121908841, CM001823, CM030108, COSV53215406, COSV53221840; ClinVar: pathogenic; called by muse, mutect2
- AAMDC | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 42/255 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.549); catalogued as rs368865821; called by muse, mutect2, varscan2
- ABCA1 | c.6599G>A p.R2200Q | Missense Mutation (SNP) | VAF 54/290 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as rs751669145, COSV66071642; called by muse, mutect2, varscan2
- ACADL | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 48/273 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs952281925, COSV52054916; called by muse, mutect2, varscan2
- ACTL6A | c.1151A>T p.N384I | Missense Mutation (SNP) | VAF 89/231 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); catalogued as COSV52024251; called by muse, mutect2, varscan2
- ACTR8 | c.1280C>T p.A427V | Missense Mutation (SNP) | VAF 10/270 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.173); catalogued as COSV99213688; called by muse, mutect2
- ADAMTS3 | c.3356G>A p.R1119K | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.01); catalogued as COSV54404988; called by muse, mutect2, varscan2
- ADGRF3 | c.3095G>A p.R1032H (on ENST00000311519 / NM_001145168.1; = p.R833H on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.023); catalogued as rs1250347432, COSV61050885, COSV61053856; called by muse, mutect2, varscan2
- ADGRF3 | c.1103C>T p.A368V (on ENST00000311519 / NM_001145168.1; = p.A169V on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs148181027; called by muse, mutect2, varscan2
- AIG1 | c.502G>T p.G168C | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as COSV51623133; called by muse, mutect2
- ANKRA2 | c.626A>C p.Q209P | Missense Mutation (SNP) | VAF 15/181 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.447); catalogued as COSV99707011; called by muse, mutect2
- ANKRD30A | c.1252G>A p.A418T (on ENST00000611781; = p.A362T on NM_052997.2) | Missense Mutation (SNP) | VAF 13/190 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs372362957; called by muse, mutect2
- AP4B1 | c.2122A>G p.I708V | Missense Mutation (SNP) | VAF 7/170 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99870756; called by muse, mutect2
- APC | c.8336C>T p.A2779V | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs1561622448, COSV57388989; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APEH | c.870del p.K291Sfs*17 | Frame Shift Del (DEL) | VAF 84/286 reads (29%) | catalogued as rs768993340, COSV56533158; called by mutect2, pindel, varscan2
- APOB | c.10894A>G p.R3632G | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV51956582; called by muse, mutect2, varscan2
- APOBEC3H | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62379253; called by muse, mutect2, varscan2
- ARHGAP31 | c.1063G>A p.V355M | Missense Mutation (SNP) | VAF 13/279 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); catalogued as COSV99957034; called by muse, mutect2
- ARHGAP6 | c.2340G>A p.W780* (on ENST00000337414 / NM_013427.3; = p.W577* on NM_013423.3) | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV57304782; called by muse, mutect2, varscan2
- ARHGEF16 | c.940A>G p.K314E | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1377045352, COSV65683483; called by muse, mutect2, varscan2
- ASPM | c.9121A>G p.R3041G | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99659498; called by muse, mutect2
- ATAD5 | c.2864A>G p.N955S | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV58980046; called by muse, mutect2, varscan2
- ATP10B | c.3829G>A p.V1277I | Missense Mutation (SNP) | VAF 61/165 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.147); catalogued as rs757825777, COSV59166719; called by muse, mutect2, varscan2
- ATP11C | c.1104G>A p.M368I | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV59576155; called by muse, mutect2, varscan2
- BAZ1A | c.3463C>T p.R1155* | Nonsense Mutation (SNP) | VAF 16/320 reads (5%) | catalogued as rs921729277, COSV100701137; called by muse, mutect2
- BAZ2B | c.4693C>T p.R1565* | Nonsense Mutation (SNP) | VAF 38/221 reads (17%) | catalogued as COSV58596127, COSV58611614; called by muse, mutect2, varscan2
- BCAN | c.1299A>T p.E433D | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV61260119; called by muse, mutect2, varscan2
- BCL6 | c.1948C>T p.R650* | Nonsense Mutation (SNP) | VAF 21/128 reads (16%) | catalogued as COSV51656362; called by muse, mutect2, varscan2
- BCORL1 | c.5042del p.P1681Qfs*20 | Frame Shift Del (DEL) | VAF 18/53 reads (34%) | catalogued as rs768244116; called by mutect2, pindel, varscan2
- BRCA2 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 14/324 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555281093, COSV101204178; ClinVar: uncertain significance; called by muse, mutect2
- BTRC | c.484C>T p.H162Y (on ENST00000370187 / NM_033637.4; = p.H126Y on NM_003939.5) | Missense Mutation (SNP) | VAF 11/228 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV100926546; called by muse, mutect2
- C2CD6 | c.923C>G p.S308C | Missense Mutation (SNP) | VAF 55/208 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV53801503; called by muse, mutect2, varscan2
- CACNB3 | c.217G>A p.V73I | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs901128138, COSV56396951; called by muse, mutect2
- CACNG5 | c.627G>A p.M209I | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV50060977; called by muse, varscan2
- CADPS2 | c.1859A>G p.K620R | Missense Mutation (SNP) | VAF 59/191 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV57389625; called by muse, mutect2, varscan2
- CAMK2A | c.1109C>T p.T370M (on ENST00000348628 / NM_171825.2; = p.T381M on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.849); catalogued as COSV62248071; called by muse, mutect2, varscan2
- CAMSAP3 | c.917T>C p.M306T | Missense Mutation (SNP) | VAF 55/171 reads (32%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV50375984; called by muse, mutect2, varscan2
- CASS4 | c.1618C>T p.R540C | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs186338077, COSV64388797; called by muse, mutect2, varscan2
- CASS4 | c.1768C>T p.R590W | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs199513148, COSV64388802; called by muse, mutect2, varscan2
- CCDC60 | c.1232G>A p.R411H | Missense Mutation (SNP) | VAF 19/193 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); catalogued as rs376048694; called by muse, mutect2, varscan2
- CCNJL | c.139A>G p.T47A | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as COSV57447446; called by muse, mutect2, varscan2
- CD101 | c.2721C>G p.Y907* | Nonsense Mutation (SNP) | VAF 10/164 reads (6%) | catalogued as COSV99869501, COSV99869812; called by muse, mutect2
- CD3D | c.431G>A p.R144K | Missense Mutation (SNP) | VAF 148/456 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52676499; called by muse, mutect2, varscan2
- CD3E | c.386C>T p.S129L | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs563868055, COSV62346096; called by muse, mutect2, varscan2
- CD93 | c.724_726del p.E242del | In Frame Del (DEL) | VAF 8/62 reads (13%) | catalogued as rs1568678591; called by mutect2, pindel
- CDR2 | c.1334C>T p.T445I | Missense Mutation (SNP) | VAF 65/412 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.165); catalogued as COSV51677809; called by muse, mutect2, varscan2
- CENPX | c.211G>A p.E71K (on ENST00000392359 / NM_001271006.2; = p.E53K on NM_144998.4) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60713121; called by muse, mutect2, varscan2
- CEP126 | c.1878_1879del p.I627* | Frame Shift Del (DEL) | VAF 17/52 reads (33%) | catalogued as rs762228587, COSV54831894; called by mutect2, pindel, varscan2
- CEP170 | c.1299del p.H434Mfs*9 | Frame Shift Del (DEL) | VAF 21/218 reads (10%) | catalogued as COSV60507575; called by mutect2, pindel
- CFAP46 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs141623050; called by mutect2, varscan2
- CHD4 | c.2014C>T p.P672S (on ENST00000357008 / NM_001363606.2; = p.P685S on NM_001273.5) | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); catalogued as rs773573339, COSV100537934; called by muse, mutect2
- CHL1 | c.2503A>G p.K835E (on ENST00000397491 / NM_001253387.1; = p.K851E on NM_006614.4) | Missense Mutation (SNP) | VAF 19/189 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.19); catalogued as COSV99851052; called by muse, mutect2, varscan2
- CHMP2A | c.275C>T p.T92I | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV53398393; called by muse, mutect2, varscan2
- CNTLN | c.3922del p.M1308* | Frame Shift Del (DEL) | VAF 39/225 reads (17%) | catalogued as rs761011518, COSV99078405; called by mutect2, pindel, varscan2
- CNTNAP3 | c.3188A>G p.E1063G | Missense Mutation (SNP) | VAF 52/377 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV52677171; called by muse, varscan2
- COG3 | c.693T>G p.D231E | Missense Mutation (SNP) | VAF 14/357 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV100596502; called by muse, mutect2
- COL11A1 | c.1635del p.P546Lfs*87 | Frame Shift Del (DEL) | VAF 49/163 reads (30%) | catalogued as COSV100615079, COSV62186140; called by mutect2, pindel, varscan2
- COL22A1 | c.4104G>A p.P1368= | Splice Region (SNP) | VAF 13/110 reads (12%) | catalogued as rs769862699, COSV57325231, COSV57342318; called by muse, mutect2, varscan2
- COL5A3 | c.3881C>T p.P1294L | Missense Mutation (SNP) | VAF 117/364 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs370314737, COSV53417550; called by muse, mutect2, varscan2
- CORO7-PAM16 | c.2774C>T p.A925V | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.41); catalogued as rs759272698, COSV52112261; called by muse, mutect2, varscan2
- CPAMD8 | c.269C>A p.A90E (on ENST00000651564; = p.A43E on NM_015692.5) | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as rs201146129, COSV52241350; called by muse, mutect2, varscan2
- CPNE9 | c.1238C>T p.A413V | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs762524744, COSV56070190; called by muse, mutect2, varscan2
- CPT1A | c.736G>T p.G246W | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV55762256; called by muse, mutect2, varscan2
- CRAT | c.536_538del p.S179del | In Frame Del (DEL) | VAF 32/128 reads (25%) | catalogued as rs774741037; called by pindel, varscan2
- CSGALNACT2 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs201853037; called by muse, mutect2, varscan2
- CTSK | c.616C>T p.Q206* | Nonsense Mutation (SNP) | VAF 19/192 reads (10%) | catalogued as COSV99648707; called by muse, mutect2, varscan2
- CWH43 | c.1926del p.K642Nfs*19 | Frame Shift Del (DEL) | VAF 24/230 reads (10%) | catalogued as COSV56936283; called by mutect2, pindel, varscan2
- DCBLD1 | c.599G>A p.C200Y | Missense Mutation (SNP) | VAF 14/462 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99757552; called by muse, mutect2
- DDR2 | c.565G>T p.D189Y | Missense Mutation (SNP) | VAF 8/147 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100906509; called by muse, mutect2
- DDX27 | c.2072dup p.E693Gfs*11 | Frame Shift Ins (INS) | VAF 30/112 reads (27%) | catalogued as rs766714372; called by mutect2, varscan2
- DHRS7B | c.521C>T p.T174M | Missense Mutation (SNP) | VAF 118/342 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs749445087, COSV60888687; called by mutect2, varscan2
- DHX30 | c.1223C>T p.A408V (on ENST00000445061 / NM_138615.3; = p.A369V on NM_014966.3) | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as COSV53143785; called by muse, mutect2, varscan2
- DLC1 | c.1850G>A p.R617Q (on ENST00000276297 / NM_001348081.2; = p.R180Q on NM_006094.5) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.827); catalogued as rs375103328, COSV52331872; called by muse, mutect2, varscan2
- DLGAP2 | c.2902C>T p.R968W | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as rs756769347, COSV70102646; called by muse, mutect2, varscan2
- DNAAF4 | c.1216G>A p.A406T | Missense Mutation (SNP) | VAF 16/388 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.177); catalogued as COSV100336708, COSV58247914; called by muse, mutect2
- DNAH17 | c.8488G>T p.G2830C | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV67762354; called by muse, mutect2, varscan2
- DNAH17 | c.2767G>A p.G923S | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as rs376993626, COSV67762358; called by muse, mutect2, varscan2
- DNAH7 | c.1037del p.K346Sfs*23 | Frame Shift Del (DEL) | VAF 46/148 reads (31%) | catalogued as rs761292636; called by mutect2, varscan2
- DNAH8 | c.9055A>G p.M3019V | Missense Mutation (SNP) | VAF 69/180 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as rs201157889; called by muse, mutect2, varscan2
- DOCK10 | c.2006G>T p.R669I | Missense Mutation (SNP) | VAF 34/406 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51365472, COSV99289282; called by muse, mutect2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 17/152 reads (11%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DSG1 | c.692G>A p.G231D | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs201719724, COSV57134661, COSV57140109; called by muse, mutect2, varscan2
- DYNC2H1 | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs750135569, COSV62109181; called by muse, mutect2, varscan2
- DZANK1 | c.550G>A p.G184S | Missense Mutation (SNP) | VAF 34/243 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs750742743, COSV52749149; called by muse, mutect2, varscan2
- E2F5 | c.673C>A p.H225N | Missense Mutation (SNP) | VAF 13/254 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as COSV99809456; called by muse, mutect2
- ELN | c.468A>G p.P156= | Splice Region (SNP) | VAF 37/179 reads (21%) | catalogued as COSV52716705; called by muse, mutect2, varscan2
- ELP1 | c.2459G>A p.C820Y | Missense Mutation (SNP) | VAF 41/254 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65900377; called by muse, mutect2, varscan2
- ENGASE | c.971A>G p.D324G | Missense Mutation (SNP) | VAF 19/294 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as COSV100285767; called by muse, mutect2
- ENPEP | c.205G>T p.G69C | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.078); catalogued as COSV54458768; called by muse, mutect2, varscan2
- EPC1 | c.593A>G p.K198R | Missense Mutation (SNP) | VAF 12/233 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as COSV99552889; called by muse, mutect2
- EPHA1 | c.2801T>A p.F934Y | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51977309; called by muse, mutect2, varscan2
- EPHX4 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 85/144 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749290050, COSV64889068; called by muse, mutect2, varscan2
- ERAP1 | c.2579T>G p.L860R | Missense Mutation (SNP) | VAF 14/352 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99700896; called by muse, mutect2
- ERV3-1 | c.1360G>A p.G454R | Missense Mutation (SNP) | VAF 27/354 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.781); catalogued as rs1016516080, COSV99275595; called by muse, mutect2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 53/119 reads (45%) | catalogued as rs775950025; called by mutect2, varscan2
- EVPL | c.5212C>T p.L1738F | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100044435; called by muse, mutect2
- EXOC5 | c.1819G>T p.G607* | Nonsense Mutation (SNP) | VAF 16/276 reads (6%) | catalogued as COSV100567065; called by muse, mutect2
- F12 | c.80A>C p.K27T | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV99499622; called by muse, mutect2
- F2 | c.491C>G p.T164S | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.85); PolyPhen benign (0.007); catalogued as COSV61316519, COSV61318086; called by muse, mutect2, varscan2
- FAM114A2 | c.737G>A p.G246D | Missense Mutation (SNP) | VAF 9/286 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61078657; called by muse, mutect2
- FAM13A | c.2299C>T p.P767S | Missense Mutation (SNP) | VAF 16/204 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99983518; called by muse, mutect2
- FAM209B | c.142C>A p.L48I | Missense Mutation (SNP) | VAF 14/315 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV100990963; called by muse, mutect2
- FAM47C | c.1891C>T p.R631C | Missense Mutation (SNP) | VAF 38/144 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.093); catalogued as rs140469750, COSV63724403; called by muse, mutect2, varscan2
- FANCM | c.6011C>T p.S2004L | Missense Mutation (SNP) | VAF 54/151 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as COSV57507664; called by muse, mutect2, varscan2
- FAT3 | c.2194G>A p.D732N | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV53149152, COSV53186335; called by muse, mutect2, varscan2
- FBXW8 | c.1039G>A p.G347S (on ENST00000309909; = p.G385S on NM_012174.1) | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV59304190; called by muse, mutect2, varscan2
- FCGR1A | c.818G>A p.S273N | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64986196; called by muse, mutect2, varscan2
- FECH | c.1124C>A p.P375Q | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV50493475; called by muse, mutect2, varscan2
- FHIT | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs371000765; called by muse, mutect2, varscan2
- FILIP1 | c.3289G>A p.V1097M | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.075); catalogued as rs773434761, COSV52742671; called by muse, mutect2, varscan2
- FN1 | c.1150C>A p.L384I | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as COSV104396177, COSV60566049; called by muse, mutect2, varscan2
- GABRG3 | c.1079C>T p.S360F | Missense Mutation (SNP) | VAF 65/198 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs865778068, COSV61537411; called by muse, mutect2, varscan2
- GATA2 | c.1348G>A p.G450R | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as rs370164300; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GDF9 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 51/162 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs751002918, COSV51525840; called by muse, mutect2, varscan2
- GINS4 | c.400A>G p.M134V | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs1384595320, COSV99394528; called by muse, mutect2
- GPKOW | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); catalogued as COSV50246055; called by muse, mutect2, varscan2
- GPLD1 | c.2101G>A p.A701T | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs565249214, COSV57757683; called by muse, mutect2, varscan2
- GPR142 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as rs375803625; called by muse, mutect2, varscan2
- GPR158 | c.1940A>G p.Y647C | Missense Mutation (SNP) | VAF 61/425 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs768516794, COSV66285104; called by muse, mutect2, varscan2
- GRIA3 | c.260C>T p.T87I | Missense Mutation (SNP) | VAF 11/361 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99989966; called by muse, mutect2
- GRIN3A | c.1009C>T p.R337W | Missense Mutation (SNP) | VAF 35/188 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.513); catalogued as rs773593066, COSV62459084; called by muse, mutect2, varscan2
- GRIPAP1 | c.2126C>T p.A709V | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as COSV54416380; called by muse, mutect2, varscan2
- GUSB | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 12/243 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100512548, COSV59222678; called by muse, mutect2
- HECTD1 | c.7207C>T p.L2403F | Missense Mutation (SNP) | VAF 53/161 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); catalogued as COSV67949664; called by muse, mutect2, varscan2
- HMMR | c.1238T>C p.L413S | Missense Mutation (SNP) | VAF 66/205 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62375693; called by muse, mutect2, varscan2
- HNRNPR | c.1780T>A p.W594R | Missense Mutation (SNP) | VAF 10/317 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); catalogued as COSV100164493; called by muse, mutect2
- HROB | c.811C>T p.Q271* | Nonsense Mutation (SNP) | VAF 21/96 reads (22%) | catalogued as COSV55371208; called by muse, mutect2, varscan2
- IFNAR1 | c.623C>T p.T208M | Missense Mutation (SNP) | VAF 77/242 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.358); catalogued as rs767417203, COSV54254885; called by muse, mutect2, varscan2
- IKZF2 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs767182214, COSV100563498; called by muse, mutect2
- IL6ST | c.1587del p.V530* | Frame Shift Del (DEL) | VAF 23/150 reads (15%) | catalogued as rs776023104; called by mutect2, varscan2
- INCENP | c.1691G>A p.R564Q (on ENST00000394818 / NM_001040694.2; = p.R560Q on NM_020238.3) | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as rs781521515, COSV53921941, COSV99611007; called by muse, mutect2, varscan2
- ISLR | c.1141C>T p.P381S | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as rs770211289, COSV51435141; called by muse, mutect2, varscan2
- ITCH | c.2507G>A p.R836Q (on ENST00000262650 / NM_001257137.3; = p.R795Q on NM_031483.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/318 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99392404; called by muse, mutect2
- ITFG2 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs140247675; called by muse, mutect2
- JPH2 | c.902C>T p.S301L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1475520393, COSV65902371; called by muse, mutect2, varscan2
- KANSL1 | c.611del p.G204Vfs*2 | Frame Shift Del (DEL) | VAF 47/214 reads (22%) | catalogued as rs1304078301; called by mutect2, pindel, varscan2
- KANSL3 | c.1366G>A p.V456M | Missense Mutation (SNP) | VAF 57/522 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV62624888; called by muse, mutect2, varscan2
- KAT2B | c.866G>A p.C289Y | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55430643; called by muse, mutect2
- KCNJ12 | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs782569468, COSV59174352; called by muse, mutect2, varscan2
- KCNK16 | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as COSV100949189; called by muse, mutect2, varscan2
- KCNQ3 | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66484030; called by muse, mutect2, varscan2
- KDM6B | c.2164del p.Q722Nfs*4 | Frame Shift Del (DEL) | VAF 18/58 reads (31%) | catalogued as rs748243814; called by mutect2, varscan2
- KIF26B | c.1367G>A p.R456H | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1293822425, COSV63641072; called by muse, mutect2
- KIRREL1 | c.833A>G p.Y278C | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs777767241, COSV63292076; called by muse, mutect2, varscan2
- KMT2A | c.10346A>C p.H3449P | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV63293587; called by muse, mutect2, varscan2
- KMT2D | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV56407319, COSV56493934; called by muse, mutect2, varscan2
- KRBOX4 | c.421C>G p.Q141E (on ENST00000344302 / NM_001129898.2; = p.Q136E on NM_017776.2) | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); catalogued as COSV99994250; called by muse, mutect2
- KRT4 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as rs199642796; called by muse, mutect2
- KRT73 | c.635G>T p.R212L | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV59837684, COSV99988492; called by muse, mutect2
- KRTAP17-1 | c.284G>A p.C95Y | Missense Mutation (SNP) | VAF 51/198 reads (26%) | PolyPhen probably damaging (0.991); catalogued as COSV61972644; called by muse, mutect2, varscan2
- LAMB1 | c.1580G>A p.G527D | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV55971385; called by muse, mutect2, varscan2
- LAMC1 | c.2109G>T p.M703I | Missense Mutation (SNP) | VAF 102/327 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV51187157; called by muse, mutect2, varscan2
- LDB1 | c.640G>A p.A214T (on ENST00000425280 / NM_001321612.2; = p.A178T on NM_003893.5) | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.898); catalogued as COSV100756387; called by muse, mutect2
- LGR5 | c.952A>G p.I318V | Missense Mutation (SNP) | VAF 19/342 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.036); catalogued as COSV57009968, COSV99877861; called by muse, mutect2
- LILRA4 | c.708del p.G237Efs*4 | Frame Shift Del (DEL) | VAF 20/73 reads (27%) | catalogued as COSV99393439; called by mutect2, pindel, varscan2
- LIMD1 | c.60G>C p.M20I | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV56270886; called by muse, mutect2, varscan2
- LIPA | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 42/255 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1449945329, COSV51081095; called by muse, mutect2, varscan2
- LIX1L | c.673A>C p.K225Q | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV63417362; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 56/412 reads (14%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LMTK2 | c.919C>G p.R307G | Missense Mutation (SNP) | VAF 57/184 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV52005087, COSV52005689; called by muse, mutect2, varscan2
- LPCAT1 | c.1423G>A p.D475N | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV52041930; called by muse, mutect2, varscan2
- LRFN5 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 69/177 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs745814679, COSV53261964; called by muse, varscan2
- LRFN5 | c.445C>A p.L149I | Missense Mutation (SNP) | VAF 58/174 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.919); catalogued as COSV53278739; called by muse, varscan2
- LRRC74A | c.1267C>T p.H423Y | Missense Mutation (SNP) | VAF 88/296 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as COSV53612791; called by muse, mutect2, varscan2
- LTF | c.239G>A p.G80D | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as COSV51612792; called by muse, mutect2, varscan2
- LUC7L3 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV99536881; called by muse, mutect2
- MACF1 | c.20615C>T p.T6872M (on ENST00000372915; = p.T4917M on NM_012090.5) | Missense Mutation (SNP) | VAF 8/114 reads (7%) | catalogued as rs937469263, COSV57138041; called by muse, mutect2
- MAGEB10 | c.997G>A p.G333S | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1212381828, COSV63310687; called by muse, mutect2, varscan2
- MED13L | c.3497C>T p.A1166V | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56132346; called by muse, mutect2, varscan2
- MED13L | c.1730C>A p.P577H | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56132356; called by muse, mutect2, varscan2
- MED23 | c.136C>T p.Q46* | Nonsense Mutation (SNP) | VAF 60/205 reads (29%) | catalogued as COSV63438061; called by muse, mutect2, varscan2
- MEX3B | c.1535G>A p.R512H | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.056); catalogued as rs1192061493, COSV61664554; called by muse, mutect2, varscan2
- MMRN1 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.129); catalogued as rs996930856, COSV53335076; called by muse, mutect2
- MTMR1 | c.1171G>A p.V391M | Missense Mutation (SNP) | VAF 8/211 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV100953089; called by muse, mutect2
- MYBPC3 | c.127C>T p.Q43* | Nonsense Mutation (SNP) | VAF 11/39 reads (28%) | catalogued as rs892087411, COSV57034815; called by muse, mutect2, varscan2
- MYBPH | c.488T>C p.I163T | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as COSV99703934; called by muse, mutect2
- MYH14 | c.1256G>T p.R419L | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV51819425, COSV99222586; called by muse, mutect2
- MYH3 | c.358G>T p.G120C | Missense Mutation (SNP) | VAF 10/325 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99878149; called by muse, mutect2
- MYO15A | c.1282G>A p.A428T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs1555538616, COSV52756629, COSV99232494; called by muse, mutect2
- MYO3B | c.2129+1G>A p.X710_splice | Splice Site (SNP) | VAF 17/55 reads (31%) | catalogued as rs1472803521, COSV58720770; called by muse, mutect2, varscan2
- NAP1L5 | c.386G>T p.G129V | Missense Mutation (SNP) | VAF 32/190 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV52025984; called by muse, varscan2
- NAV3 | c.2861A>G p.H954R | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as rs1030311441, COSV99890261; called by muse, mutect2
- NCOA7 | c.644A>G p.E215G | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV57662385; called by muse, mutect2, varscan2
- NEXMIF | c.2110G>T p.A704S | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV50044180, COSV99280640; called by muse, mutect2
- NFASC | c.1934G>A p.R645Q (on ENST00000339876 / NM_001378329.1; = p.R641Q on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.304); catalogued as rs1448561271, COSV58383835; called by muse, mutect2, varscan2
- NOTCH1 | c.2294G>C p.G765A | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV53080426, COSV99487594; called by muse, mutect2
- NPM2 | c.586A>G p.S196G | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV99235723; called by muse, mutect2
- NR1D1 | c.965G>A p.S322N | Missense Mutation (SNP) | VAF 72/216 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV52846941; called by muse, mutect2, varscan2
- NSRP1 | c.139A>G p.R47G | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV55935942; called by muse, mutect2, varscan2
- OMD | c.1049T>C p.I350T | Missense Mutation (SNP) | VAF 173/506 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as rs905388975, COSV65020576; called by muse, mutect2, varscan2
- OR2B11 | c.338G>A p.C113Y | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV59511882; called by muse, mutect2, varscan2
- OR2T12 | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as rs1409983118, COSV58779975; called by muse, mutect2, varscan2
- OR4B1 | c.143G>A p.S48N | Missense Mutation (SNP) | VAF 130/332 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV58884314; called by muse, mutect2, varscan2
- OR51S1 | c.82C>A p.L28I | Missense Mutation (SNP) | VAF 7/181 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100437458; called by muse, mutect2
- OR5F1 | c.661G>A p.V221I | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs530485082, COSV53549243; called by muse, mutect2, varscan2
- OR7A10 | c.260C>T p.T87I | Missense Mutation (SNP) | VAF 25/278 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.101); catalogued as COSV99932436; called by muse, mutect2
- OSBPL6 | c.1255C>T p.Q419* | Nonsense Mutation (SNP) | VAF 29/144 reads (20%) | catalogued as COSV51932812; called by muse, mutect2, varscan2
- OTOP3 | c.1612G>A p.G538R | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs753881983, COSV60915358; called by muse, mutect2
- P2RX1 | c.841G>A p.E281K | Missense Mutation (SNP) | VAF 51/167 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.095); catalogued as rs1421043537, COSV56653199; called by muse, mutect2, varscan2
- PACRGL | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 72/406 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs183601092; called by muse, mutect2, varscan2
- PAN3 | c.1349G>A p.R450Q | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as rs1426808022, COSV56702102; called by muse, mutect2
- PCDHA9 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 17/205 reads (8%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.001); catalogued as rs1223339539, COSV100969466; called by muse, mutect2
- PCDHGB5 | c.1927C>T p.R643C | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV54009202; called by muse, mutect2
- PDCD7 | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 118/325 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); catalogued as rs1016835805, COSV52601669; called by muse, mutect2, varscan2
- PDE10A | c.1812G>T p.Q604H | Missense Mutation (SNP) | VAF 6/126 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs1033417971, COSV100604143; called by muse, mutect2
- PDILT | c.1000C>A p.P334T | Missense Mutation (SNP) | VAF 16/390 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100199350; called by muse, mutect2
- PGR | c.2695C>T p.R899W | Missense Mutation (SNP) | VAF 13/312 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as COSV54799223, COSV54801600; called by muse, mutect2
- PHF24 | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 5/105 reads (5%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.585); catalogued as rs894237442, COSV99646319; called by muse, mutect2
- PHF6 | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 20/520 reads (4%) | catalogued as COSV100136461; called by muse, mutect2
- PHLPP2 | c.547G>A p.V183I | Missense Mutation (SNP) | VAF 53/84 reads (63%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.979); catalogued as rs771597217, COSV62427732; called by muse, mutect2, varscan2
- PIK3CB | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 10/316 reads (3%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.523); catalogued as rs1217537873, COSV56683158; called by muse, mutect2
- PKD1L1 | c.2365C>T p.H789Y | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs764057809, COSV56980341; called by muse, mutect2, varscan2
- PLEKHF2 | c.350C>T p.T117M | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.745); catalogued as rs374267775; called by muse, mutect2, varscan2
- PLEKHG2 | c.3903del p.A1302Qfs*57 | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | catalogued as rs748579666; called by mutect2, pindel, varscan2
- PLXNB2 | c.5337+2T>G p.X1779_splice | Splice Site (SNP) | VAF 12/178 reads (7%) | catalogued as COSV100834032; called by muse, mutect2
- PNO1 | c.569C>A p.T190N | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV99721465; called by muse, mutect2, varscan2
- PNPLA4 | c.58G>T p.G20W | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101124379; called by muse, mutect2
- PPP2R1A | c.892G>C p.V298L | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV59049216; called by muse, mutect2, varscan2
- PRDM16 | c.2692-1G>T p.X898_splice | Splice Site (SNP) | VAF 5/55 reads (9%) | catalogued as COSV54604395, COSV54612199; called by muse, mutect2
- PRDM4 | c.1489G>T p.E497* | Nonsense Mutation (SNP) | VAF 11/223 reads (5%) | catalogued as COSV99946455, COSV99946564; called by muse, mutect2
- PRIMA1 | c.394G>A p.V132I | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.085); catalogued as rs761493685, COSV100301246; called by muse, mutect2
- PSMD5 | c.990G>T p.Q330H | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.06); catalogued as COSV52962304; called by muse, mutect2, varscan2
- PUSL1 | c.529_531del p.D177del | In Frame Del (DEL) | VAF 10/14 reads (71%) | catalogued as rs776346419; called by mutect2, varscan2
- PYGM | c.1117T>C p.C373R | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs985454554, COSV99377053; called by muse, mutect2
- RANBP17 | c.277G>A p.V93M | Missense Mutation (SNP) | VAF 69/224 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as rs531086103, COSV66658614; called by muse, mutect2, varscan2
- RASA1 | c.685C>T p.H229Y | Missense Mutation (SNP) | VAF 103/329 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57203523; called by muse, mutect2, varscan2
- RBM43 | c.406del p.I136Sfs*4 | Frame Shift Del (DEL) | VAF 27/68 reads (40%) | catalogued as rs142934811, CD1212851; called by mutect2, varscan2
- RBMS3 | c.676G>T p.G226* | Nonsense Mutation (SNP) | VAF 12/308 reads (4%) | catalogued as COSV99821035; called by muse, mutect2
- RGS12 | c.4087del p.Q1363Rfs*30 (on ENST00000336727; = p.Q1363Rfs*22 on NM_002926.3) | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | catalogued as rs781771156; called by mutect2, varscan2
- RHPN1 | c.400T>G p.F134V | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as COSV100000626; called by muse, mutect2
- RNF175 | c.935C>A p.P312H | Missense Mutation (SNP) | VAF 39/239 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52608562; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 44/121 reads (36%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RRBP1 | c.2218G>T p.G740W (on ENST00000377813 / NM_001365613.2; = p.G307W on NM_004587.3) | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as COSV55703857, COSV99853931; called by muse, mutect2
- RXFP1 | c.2088G>T p.W696C | Missense Mutation (SNP) | VAF 62/162 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV57057853; called by muse, mutect2, varscan2
- SALL1 | c.3555G>A p.M1185I | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV99173595; called by muse, mutect2
- SCAF8 | c.223C>T p.H75Y | Missense Mutation (SNP) | VAF 20/386 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1451022175, COSV100914068; called by muse, mutect2
- SCN8A | c.5623G>A p.A1875T | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as rs1274667201, COSV61994283; called by muse, mutect2, varscan2
- SEC11A | c.290G>T p.R97L | Missense Mutation (SNP) | VAF 26/347 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99190009; called by muse, mutect2
- SEC14L5 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 7/180 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.631); catalogued as rs955243183, COSV99228654, COSV99229506; called by muse, mutect2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 48/232 reads (21%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEMA3A | c.777A>C p.K259N | Missense Mutation (SNP) | VAF 16/284 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV99546419; called by muse, mutect2
- SERAC1 | c.227_228dup p.V77Mfs*7 | Frame Shift Ins (INS) | VAF 83/301 reads (28%) | catalogued as rs886041750; called by mutect2, varscan2
- SET | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1181003970, COSV65518041; called by muse, mutect2, varscan2
- SFRP2 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.362); catalogued as COSV56838549; called by muse, mutect2, varscan2
- SH2D4B | c.486G>T p.E162D | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.584); catalogued as COSV57902581; called by muse, mutect2, varscan2
- SLC23A1 | c.1235C>G p.T412S | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV62297853; called by muse, mutect2, varscan2
- SLC26A9 | c.1978G>A p.V660I | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs908623194, COSV100536331; called by muse, mutect2
- SLC2A3 | c.263T>C p.F88S | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50008804; called by muse, mutect2, varscan2
- SLC45A1 | c.402C>A p.F134L | Missense Mutation (SNP) | VAF 103/313 reads (33%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.996); catalogued as COSV57095056, COSV57101489; called by muse, varscan2
- SLC4A2 | c.1093G>A p.V365M | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs750757384, COSV59659660; called by muse, mutect2, varscan2
- SLCO2B1 | c.2096G>T p.G699V | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.579); catalogued as COSV56940381; called by muse, mutect2, varscan2
- SLIT2 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs1381268895, COSV56569631; called by muse, mutect2
- SNAPC1 | c.460C>T p.R154* | Nonsense Mutation (SNP) | VAF 60/174 reads (34%) | catalogued as rs777173078, COSV53521634; called by muse, mutect2, varscan2
- SPEG | c.4795G>A p.D1599N | Missense Mutation (SNP) | VAF 16/232 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1342717789, COSV100404339; called by muse, mutect2
- SPPL2C | c.1546G>C p.A516P | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100234006, COSV61293966; called by muse, mutect2, varscan2
- SSUH2 | c.371C>A p.P124H | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58034114; called by muse, mutect2, varscan2
- SSX7 | c.466+1G>A p.X156_splice | Splice Site (SNP) | VAF 45/552 reads (8%) | catalogued as COSV99993840; called by muse, mutect2
- STIL | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 31/247 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750455029, COSV54554544; called by muse, mutect2, varscan2
- STIP1 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 20/251 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs775263263, COSV100534853; called by muse, mutect2
- STK3 | c.329T>C p.I110T | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1427248002, COSV101372514; called by muse, mutect2
- SYT12 | c.352C>T p.R118W | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as rs1414894611, COSV67355263; called by muse, mutect2, varscan2
- TAF1C | c.1462C>T p.L488F | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs1307719141, COSV58989837; called by muse, mutect2, varscan2
- TAF1L | c.705G>A p.M235I | Missense Mutation (SNP) | VAF 36/240 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs781526101, COSV54271465; called by muse, mutect2, varscan2
- TBC1D1 | c.1277A>G p.Q426R | Missense Mutation (SNP) | VAF 16/156 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54728634; called by muse, mutect2, varscan2
- TBC1D23 | c.1947del p.K649Nfs*18 (on ENST00000394144 / NM_001199198.3; = p.K634Nfs*18 on NM_018309.5) | Frame Shift Del (DEL) | VAF 40/142 reads (28%) | catalogued as rs747637295, COSV61367528; called by mutect2, varscan2
- TBX20 | c.387G>A p.M129I | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV68786243; called by muse, mutect2, varscan2
- TEK | c.2743C>T p.R915C | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66229101; called by muse, mutect2, varscan2
- TJP2 | c.1490G>A p.R497H | Missense Mutation (SNP) | VAF 83/505 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.511); catalogued as rs532438219, COSV55263337, COSV55268291; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TLDC2 | c.380G>A p.S127N | Missense Mutation (SNP) | VAF 51/274 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV54116058; called by muse, mutect2, varscan2
- TLR7 | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.39); catalogued as rs755359069, COSV66125798; called by muse, mutect2, varscan2
- TM4SF4 | c.36del p.T13Pfs*23 | Frame Shift Del (DEL) | VAF 32/220 reads (15%) | catalogued as rs747355584; called by mutect2, pindel, varscan2
- TMC1 | c.1978C>T p.P660S | Missense Mutation (SNP) | VAF 16/366 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1303007203, COSV99919305; called by muse, mutect2
- TMC1 | c.2069C>T p.A690V | Missense Mutation (SNP) | VAF 103/321 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as rs371947894; called by muse, mutect2, varscan2
- TMEM62 | c.1877A>C p.N626T | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.137); catalogued as COSV53043628; called by muse, mutect2, varscan2
- TMEM63A | c.267-1G>A p.X89_splice | Splice Site (SNP) | VAF 8/128 reads (6%) | catalogued as rs1376579096, COSV100834366; called by muse, mutect2
- TMTC1 | c.1733G>A p.G578D (on ENST00000539277 / NM_001193451.2; = p.G470D on NM_175861.3) | Missense Mutation (SNP) | VAF 28/302 reads (9%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.967); catalogued as COSV99759537; called by muse, mutect2
- TNK1 | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs563727404, COSV61172819; called by muse, mutect2, varscan2
- TNN | c.2893G>T p.A965S | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.871); catalogued as COSV99511869; called by muse, mutect2
- TNPO2 | c.2041C>T p.R681W | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1164109661, COSV100790349; called by muse, mutect2
- TNRC6A | c.1040C>G p.T347S | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.656); catalogued as COSV59371142; called by muse, mutect2, varscan2
- TRA2B | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 108/398 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.582); catalogued as COSV52025194; called by mutect2, varscan2
- TRMT9B | c.465C>A p.D155E | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748847588, COSV101501632, COSV71600863; called by muse, mutect2, varscan2
- TRPV4 | c.1389G>A p.W463* | Nonsense Mutation (SNP) | VAF 20/131 reads (15%) | catalogued as COSV55686493; called by muse, mutect2, varscan2
- TRRAP | c.8432C>T p.P2811L (on ENST00000359863 / NM_001244580.1; = p.P2793L on NM_003496.3) | Missense Mutation (SNP) | VAF 68/191 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs767932205, COSV62842472, COSV62856185; called by muse, mutect2, varscan2
- TSHZ3 | c.1864G>A p.A622T | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.188); catalogued as COSV53685417, COSV99550664; called by muse, mutect2, varscan2
- TTC39A | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52962145; called by muse, mutect2, varscan2
- TTN | c.3963G>T p.K1321N (on ENST00000591111; = p.K1275N on NM_003319.4) | Missense Mutation (SNP) | VAF 35/97 reads (36%) | PolyPhen probably damaging (0.997); catalogued as COSV60404290; called by muse, mutect2, varscan2
- TUBGCP2 | c.524C>A p.P175H | Missense Mutation (SNP) | VAF 17/515 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99427605; called by muse, mutect2
- TXLNA | c.790C>T p.R264W | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1031447030, COSV101009840; called by muse, mutect2
- UBE2L6 | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.058); catalogued as rs868642148, COSV54702734; called by muse, mutect2
- UBE3C | c.3247A>G p.S1083G | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61955992; called by muse, mutect2, varscan2
- UBR1 | c.2083C>T p.L695F | Missense Mutation (SNP) | VAF 50/152 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51937714; called by muse, mutect2, varscan2
- UFD1 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 52/300 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as COSV54249247; called by muse, mutect2, varscan2
- UGT1A1 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.806); catalogued as COSV59400931; called by muse, mutect2, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 56/188 reads (30%) | catalogued as rs767420916; called by mutect2, varscan2
- URGCP | c.2207C>T p.A736V (on ENST00000453200 / NM_001077663.3; = p.A727V on NM_017920.4) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.124); catalogued as COSV56253871, COSV99787244; called by muse, mutect2
- VPS33B | c.1345G>A p.G449R | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs765841703, COSV60980410; called by muse, mutect2, varscan2
- WBP1 | c.551dup p.H185Sfs*5 | Frame Shift Ins (INS) | VAF 18/51 reads (35%) | catalogued as rs547055147; called by mutect2, varscan2
- WDR49 | c.451G>A p.V151I (on ENST00000308378 / NM_001366158.1; = p.V492I on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as rs756311911, COSV57719427; called by muse, mutect2, varscan2
- WDR55 | c.1022dup p.G343Rfs*15 | Frame Shift Ins (INS) | VAF 28/112 reads (25%) | catalogued as rs746919573; called by mutect2, varscan2
- WFDC3 | c.263G>T p.R88M | Missense Mutation (SNP) | VAF 14/249 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV99714555; called by muse, mutect2
- WHRN | c.1354G>A p.G452S | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as rs1277906388, COSV54335266; called by muse, mutect2, varscan2
- WT1 | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 61/429 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV60066225; called by muse, mutect2, varscan2
- XIRP2 | c.91C>T p.R31W (on ENST00000628543; = p.R206W on NM_152381.6) | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1375329184, COSV54699057, COSV54700656; called by muse, mutect2, varscan2
- ZC3H12B | c.1853G>A p.R618H | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT tolerated (0.99); PolyPhen possibly damaging (0.77); catalogued as rs1477656531, COSV100161712; called by muse, mutect2
- ZFHX4 | c.8319T>A p.F2773L | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0.12); catalogued as COSV51501012; called by muse, mutect2, varscan2
- ZMIZ1 | c.1557del p.M520* | Frame Shift Del (DEL) | VAF 20/160 reads (13%) | catalogued as COSV57893266; called by mutect2, pindel, varscan2
- ZNF333 | c.347T>C p.I116T | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV99469080; called by muse, mutect2
- ZNF33A | c.2258G>A p.C753Y (on ENST00000458705 / NM_006974.3; = p.C754Y on NM_006954.2) | Missense Mutation (SNP) | VAF 10/292 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV100275755; called by muse, mutect2
- ZNF408 | c.1313C>T p.A438V | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.7); PolyPhen benign (0.018); catalogued as COSV61239591; called by mutect2, varscan2
- ZNF423 | c.595G>A p.D199N (on ENST00000563137 / NM_001379286.1; = p.D191N on NM_015069.4) | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs867011137, COSV52180778; called by muse, mutect2, varscan2
- ZNF554 | c.67G>T p.G23* | Nonsense Mutation (SNP) | VAF 36/89 reads (40%) | catalogued as COSV57887289; called by muse, mutect2, varscan2
- ZNF711 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 28/528 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1200240972, COSV99340992; called by muse, mutect2
- ZPBP2 | c.279G>T p.Q93H (on ENST00000348931 / NM_199321.3; = p.Q71H on NM_198844.3) | Missense Mutation (SNP) | VAF 33/255 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV62375872; called by muse, mutect2, varscan2
- ACACA | c.7021A>T p.I2341F | Missense Mutation (SNP) | VAF 116/337 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ATF2 | c.318del p.M107Cfs*3 | Frame Shift Del (DEL) | VAF 87/313 reads (28%) | called by mutect2, pindel, varscan2
- B3GNT5 | c.1047del p.F349Lfs*8 | Frame Shift Del (DEL) | VAF 21/84 reads (25%) | called by mutect2, pindel, varscan2
- CCT8L2 | c.1654del p.I552Sfs*4 | Frame Shift Del (DEL) | VAF 60/168 reads (36%) | called by mutect2, varscan2
- CDC42BPB | c.1026dup p.E343* | Frame Shift Ins (INS) | VAF 67/209 reads (32%) | called by mutect2, pindel, varscan2
- CDS1 | c.777del p.F259Lfs*10 | Frame Shift Del (DEL) | VAF 33/260 reads (13%) | called by mutect2, pindel, varscan2
- CFAP65 | c.1896del p.M633* | Frame Shift Del (DEL) | VAF 5/17 reads (29%) | called by mutect2, pindel
- CHD7 | c.8962del p.D2988Mfs*3 | Frame Shift Del (DEL) | VAF 15/47 reads (32%) | called by mutect2, pindel, varscan2
- CPS1 | c.84del p.K28Nfs*29 | Frame Shift Del (DEL) | VAF 39/177 reads (22%) | called by mutect2, pindel, varscan2
- DHX29 | c.3908_3910del p.E1303del | In Frame Del (DEL) | VAF 30/169 reads (18%) | called by mutect2, pindel, varscan2
- DNAH3 | c.5408del p.N1803Ifs*2 | Frame Shift Del (DEL) | VAF 63/203 reads (31%) | called by mutect2, pindel, varscan2
- EVPL | c.3497del p.N1166Tfs*8 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | called by mutect2, pindel, varscan2
- FCAMR | c.196del p.R66Dfs*44 | Frame Shift Del (DEL) | VAF 21/106 reads (20%) | called by mutect2, pindel, varscan2
- FLVCR2 | c.493del p.A165Pfs*3 | Frame Shift Del (DEL) | VAF 13/43 reads (30%) | called by mutect2, pindel, varscan2
- GGNBP2 | c.549G>T p.W183C | Missense Mutation (SNP) | VAF 16/517 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GPR151 | c.311G>A p.W104* | Nonsense Mutation (SNP) | VAF 11/224 reads (5%) | called by muse, mutect2
- GSK3B | c.591del p.K197Nfs*31 | Frame Shift Del (DEL) | VAF 29/183 reads (16%) | called by mutect2, pindel, varscan2
- IGLC7 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- IL6ST | c.537del p.T180Pfs*19 | Frame Shift Del (DEL) | VAF 92/285 reads (32%) | called by mutect2, pindel, varscan2
- JCAD | c.3088del p.A1030Qfs*35 | Frame Shift Del (DEL) | VAF 10/84 reads (12%) | called by mutect2, pindel, varscan2
- JMJD1C | c.1286del p.N429Ifs*32 | Frame Shift Del (DEL) | VAF 60/637 reads (9%) | called by mutect2, pindel
- KCNC1 | c.1332_1334del p.L445del | In Frame Del (DEL) | VAF 5/48 reads (10%) | called by mutect2, pindel
- KCNE4 | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.905); called by muse, mutect2
- KCNK4 | c.430T>A p.S144T | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.017); called by muse, mutect2
- KCTD15 | c.305dup p.I103Hfs*2 | Frame Shift Ins (INS) | VAF 29/163 reads (18%) | called by mutect2, pindel, varscan2
- LMBRD2 | c.1028del p.N343Mfs*56 | Frame Shift Del (DEL) | VAF 28/207 reads (14%) | called by mutect2, pindel, varscan2
- LRRCC1 | c.1383del p.E462Rfs*14 | Frame Shift Del (DEL) | VAF 43/159 reads (27%) | called by mutect2, pindel, varscan2
- LSR | c.1269del p.S424Vfs*8 (on ENST00000361790; = p.S405Vfs*8 on NM_015925.6) | Frame Shift Del (DEL) | VAF 9/59 reads (15%) | called by mutect2, pindel, varscan2
- MYO9A | c.2003del p.N668Ifs*10 | Frame Shift Del (DEL) | VAF 20/209 reads (10%) | called by mutect2, pindel, varscan2
- NCBP1 | c.327dup p.R110Sfs*4 | Frame Shift Ins (INS) | VAF 86/287 reads (30%) | called by mutect2, pindel, varscan2
- NMT1 | c.866del p.K289Sfs*13 | Frame Shift Del (DEL) | VAF 29/98 reads (30%) | called by mutect2, pindel, varscan2
- NPTXR | c.1253G>T p.G418V | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2
- NUAK1 | c.907C>A p.H303N | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- PODXL | c.480del p.S162Afs*5 | Frame Shift Del (DEL) | VAF 70/578 reads (12%) | called by pindel, varscan2
- PPP2R3B | c.634G>A p.D212N | Missense Mutation (SNP) | VAF 12/294 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PRICKLE3 | c.1612T>A p.S538T | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.051); called by muse, mutect2
- PRKACA | c.90del p.K30Nfs*29 | Frame Shift Del (DEL) | VAF 22/82 reads (27%) | called by mutect2, pindel, varscan2
- RALGAPB | c.1142del p.P381Hfs*11 | Frame Shift Del (DEL) | VAF 54/389 reads (14%) | called by mutect2, pindel, varscan2
- RORA | c.452del p.K151Sfs*32 (on ENST00000335670 / NM_134261.3; = p.K176Sfs*32 on NM_002943.3) | Frame Shift Del (DEL) | VAF 25/113 reads (22%) | called by mutect2, pindel, varscan2
- SFXN3 | c.853del p.L285Cfs*14 | Frame Shift Del (DEL) | VAF 41/310 reads (13%) | called by mutect2, pindel, varscan2
- SGK2 | c.586G>T p.A196S | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.867); called by muse, mutect2
- SMC2 | c.1914dup p.V639Sfs*4 | Frame Shift Ins (INS) | VAF 97/298 reads (33%) | called by mutect2, pindel, varscan2
- TDRD6 | c.1563_1564del p.C521Wfs*8 | Frame Shift Del (DEL) | VAF 27/119 reads (23%) | called by pindel, varscan2
- TECTA | c.903del p.Y302Tfs*77 | Frame Shift Del (DEL) | VAF 25/157 reads (16%) | called by mutect2, pindel, varscan2
- TMEM38A | c.764del p.G255Vfs*32 | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | called by mutect2, pindel, varscan2
- TTC3 | c.5387del p.P1796Lfs*9 | Frame Shift Del (DEL) | VAF 13/47 reads (28%) | called by mutect2, pindel, varscan2
- YES1 | c.1406del p.G469Afs*9 | Frame Shift Del (DEL) | VAF 76/217 reads (35%) | called by mutect2, pindel, varscan2
- ZG16B | c.143del p.G48Afs*34 | Frame Shift Del (DEL) | VAF 6/60 reads (10%) | called by pindel, varscan2
- ZNF540 | c.445dup p.M149Nfs*4 | Frame Shift Ins (INS) | VAF 20/161 reads (12%) | called by mutect2, varscan2
- ZNF709 | c.936del p.K312Nfs*44 | Frame Shift Del (DEL) | VAF 30/95 reads (32%) | called by mutect2, pindel, varscan2
- ABCC8 | c.3768A>G p.A1256= | Silent (SNP) | VAF 5/71 reads (7%) | catalogued as COSV100217189; called by muse, mutect2
- AC092143.1 | c.2187C>T p.S729= | Silent (SNP) | VAF 5/77 reads (6%) | catalogued as rs11554953, COSV100205768; called by muse, mutect2
- ADAMTS7 | c.2580C>T p.H860= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV66309722; called by muse, varscan2
- ADGRG4 | c.4983C>T p.T1661= | Silent (SNP) | VAF 35/111 reads (32%) | catalogued as COSV54954914; called by muse, mutect2, varscan2
- ADRA1A | c.129T>C p.G43= | Silent (SNP) | VAF 46/150 reads (31%) | catalogued as rs746933844, COSV52364580; called by muse, mutect2, varscan2
- AKAP13 | c.1194C>T p.D398= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as COSV63471768; called by muse, mutect2, varscan2
- AKAP9 | c.10056C>T p.S3352= (on ENST00000359028; = p.S3328= on NM_005751.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/138 reads (7%) | catalogued as COSV100662331; called by muse, mutect2
- AKNA | c.3144C>T p.P1048= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as rs144860883; called by mutect2, varscan2
- ANXA7 | c.84T>G p.P28= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as COSV65824637; called by muse, mutect2, varscan2
- APC | c.1575C>T p.C525= | Silent (SNP) | VAF 40/285 reads (14%) | catalogued as COSV57366014, COSV57388984; called by muse, mutect2, varscan2
- ARHGEF9 | c.1098T>C p.I366= | Silent (SNP) | VAF 45/337 reads (13%) | catalogued as COSV53645512; called by muse, mutect2, varscan2
- ATP10A | c.4458C>T p.D1486= | Silent (SNP) | VAF 12/71 reads (17%) | catalogued as rs760720206, COSV63519590, COSV63526293; called by muse, mutect2
- BPIFB1 | c.201C>T p.A67= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs1173133490, COSV53609306; called by muse, mutect2, varscan2
- BRIP1 | c.2034A>G p.A678= | Silent (SNP) | VAF 30/153 reads (20%) | catalogued as COSV52010485; called by muse, mutect2, varscan2
- C1QTNF1 | c.132G>A p.P44= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as rs375199144; called by muse, mutect2
- CAMTA1 | c.4344C>T p.D1448= | Silent (SNP) | VAF 7/108 reads (6%) | catalogued as COSV100349007; called by muse, mutect2
- CCDC150 | c.2463A>G p.A821= | Silent (SNP) | VAF 49/140 reads (35%) | catalogued as COSV55879585; called by muse, mutect2, varscan2
- CCND1 | c.318C>T p.C106= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV57123698; called by muse, mutect2, varscan2
- CD300LF | c.834T>C p.P278= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as COSV56899580; called by muse, mutect2, varscan2
- CDCA2 | c.1980C>T p.C660= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV57949051; called by muse, mutect2, varscan2
- CDS1 | c.942A>T p.V314= | Silent (SNP) | VAF 22/243 reads (9%) | catalogued as COSV99880675; called by muse, mutect2
- CELSR3 | c.2226C>A p.V742= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV50851884, COSV51175448; called by muse, mutect2, varscan2
- CKAP4 | c.522C>A p.S174= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV100952543, COSV65173349; called by muse, mutect2, varscan2
- CLCF1 | c.306G>A p.R102= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as COSV56862805; called by muse, mutect2, varscan2
- COL15A1 | c.2538T>G p.T846= | Silent (SNP) | VAF 25/163 reads (15%) | catalogued as COSV100898066, COSV66650134; called by muse, mutect2, varscan2
- COX6A2 | c.255C>T p.S85= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV99791371; called by muse, mutect2
- DAGLA | c.378C>T p.C126= | Silent (SNP) | VAF 17/132 reads (13%) | catalogued as COSV57200772; called by muse, mutect2, varscan2
- DGKG | c.2304G>A p.A768= | Silent (SNP) | VAF 66/183 reads (36%) | catalogued as rs765609936, COSV53967500; called by muse, mutect2, varscan2
- DHX15 | c.408G>A p.Q136= | Silent (SNP) | VAF 10/316 reads (3%) | catalogued as COSV100391365; called by muse, mutect2
- DOCK1 | c.3723T>G p.L1241= | Silent (SNP) | VAF 87/237 reads (37%) | catalogued as COSV54763980; called by muse, mutect2, varscan2
- DPP9 | c.1119G>A p.Q373= (on ENST00000598800; = p.Q402= on NM_139159.5) | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs1376730589, COSV99506065; called by muse, mutect2
- DPPA5 | c.198C>A p.T66= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as rs550609190, COSV64876039; called by muse, mutect2, varscan2
- E2F1 | c.1254C>T p.G418= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs769138235, COSV55775334; called by muse, mutect2, varscan2
- EEF2KMT | c.495C>T p.G165= | Silent (SNP) | VAF 10/120 reads (8%) | catalogued as COSV52157450, COSV99275727; called by muse, mutect2
- ETFBKMT | c.204G>A p.Q68= | Silent (SNP) | VAF 40/112 reads (36%) | catalogued as COSV63189762; called by muse, mutect2, varscan2
- FAM117A | c.495G>A p.T165= | Silent (SNP) | VAF 35/78 reads (45%) | catalogued as rs936996803, COSV53634245; called by muse, mutect2, varscan2
- FAT4 | c.3102C>A p.T1034= | Silent (SNP) | VAF 34/92 reads (37%) | catalogued as COSV67902731; called by muse, mutect2, varscan2
- FBF1 | c.1980G>A p.S660= (on ENST00000586717; = p.S674= on NM_001319193.1) | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as rs745341618, COSV100045094; called by muse, mutect2
- FBXL7 | c.243C>T p.T81= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs770680382, COSV100311231, COSV61646842; called by muse, mutect2
- FLT1 | c.2838G>A p.E946= | Silent (SNP) | VAF 20/441 reads (5%) | catalogued as COSV99154027; called by muse, mutect2
- FLT3 | c.2538C>T p.G846= | Silent (SNP) | VAF 22/202 reads (11%) | catalogued as COSV54073769, COSV99607381; called by muse, varscan2
- FOCAD | c.3618T>C p.A1206= | Silent (SNP) | VAF 62/398 reads (16%) | catalogued as COSV58108892; called by muse, mutect2, varscan2
- FREM2 | c.1458G>T p.G486= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV99748543; called by muse, mutect2
- FRY | c.201C>T p.L67= | Silent (SNP) | VAF 67/227 reads (30%) | catalogued as COSV66581908; called by muse, mutect2, varscan2
- GABRB1 | c.828C>T p.V276= | Silent (SNP) | VAF 80/238 reads (34%) | catalogued as rs778588040, COSV54972251, COSV54998831; called by muse, mutect2, varscan2
- GOLGB1 | c.6037C>T p.L2013= | Silent (SNP) | VAF 46/272 reads (17%) | catalogued as COSV61472238; called by muse, mutect2, varscan2
- GOSR2 | c.279T>C p.T93= (on ENST00000393456 / NM_001321134.1; = p.T111= on NM_004287.5) | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as COSV56661633; called by muse, mutect2, varscan2
- GPC2 | c.1017C>T p.S339= | Silent (SNP) | VAF 9/138 reads (7%) | catalogued as rs916825460, COSV99444656; called by muse, mutect2
- GTF2F1 | c.906T>C p.D302= | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as COSV101081200; called by muse, mutect2, varscan2
- HEATR1 | c.2229C>T p.V743= | Silent (SNP) | VAF 14/382 reads (4%) | catalogued as COSV100857616; called by muse, mutect2
- HPS3 | c.1806C>T p.Y602= | Silent (SNP) | VAF 8/233 reads (3%) | catalogued as rs1043008266, COSV56053473; called by muse, mutect2
- INPP4A | c.658T>C p.L220= | Silent (SNP) | VAF 12/224 reads (5%) | catalogued as COSV99303600; called by muse, mutect2
- IPO11 | c.2043T>C p.I681= | Silent (SNP) | VAF 56/390 reads (14%) | catalogued as COSV57583943; called by muse, mutect2, varscan2
- ITGA3 | c.1794C>T p.N598= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as COSV50348312; called by muse, mutect2, varscan2
- ITPR1 | c.6441G>A p.A2147= (on ENST00000354582; = p.A2092= on NM_002222.7) | Silent (SNP) | VAF 59/175 reads (34%) | catalogued as rs376367207; called by muse, mutect2, varscan2
- IWS1 | c.2415A>G p.A805= | Silent (SNP) | VAF 16/366 reads (4%) | catalogued as rs1047793197, COSV99767188; called by muse, mutect2
- JPH2 | c.189C>T p.Y63= | Silent (SNP) | VAF 6/130 reads (5%) | called by muse, mutect2
- KCTD19 | c.1158G>A p.T386= | Silent (SNP) | VAF 34/126 reads (27%) | catalogued as rs200198245, COSV58576492; called by muse, mutect2, varscan2
- KMT2B | c.3579C>T p.L1193= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs202127455, COSV55871026; ClinVar: likely benign; called by muse, mutect2, varscan2
- LAMP5 | c.525C>T p.P175= | Silent (SNP) | VAF 27/138 reads (20%) | catalogued as rs201803584, COSV55718341, COSV99855737; called by muse, mutect2, varscan2
- LCE2B | c.99G>A p.L33= | Silent (SNP) | VAF 60/361 reads (17%) | catalogued as rs550794184, COSV100909302; called by muse, mutect2, varscan2
- LHB | c.294C>A p.P98= | Silent (SNP) | VAF 36/97 reads (37%) | catalogued as COSV55487678; called by muse, mutect2, varscan2
- LPIN2 | c.1671C>T p.R557= | Silent (SNP) | VAF 9/175 reads (5%) | catalogued as COSV99858323; called by muse, mutect2
- LPIN3 | c.96C>T p.D32= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as rs747446012, COSV64720578; called by muse, mutect2, varscan2
- LRRC37A3 | c.3828C>T p.T1276= | Silent (SNP) | VAF 135/389 reads (35%) | catalogued as COSV58537446; called by muse, mutect2, varscan2
- LRRC40 | c.723C>A p.G241= | Silent (SNP) | VAF 10/146 reads (7%) | catalogued as COSV100918753; called by muse, mutect2
- LYRM9 | c.189C>A p.A63= | Silent (SNP) | VAF 14/244 reads (6%) | catalogued as COSV66959176; called by muse, mutect2
- LYST | c.4011C>T p.C1337= | Silent (SNP) | VAF 66/181 reads (36%) | catalogued as COSV67707050; called by muse, mutect2, varscan2
- MAP1A | c.711T>C p.A237= | Silent (SNP) | VAF 26/143 reads (18%) | catalogued as COSV55813869; called by muse, mutect2, varscan2
- MAP3K15 | c.3342C>T p.F1114= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as rs1330351180, COSV58837696; called by muse, mutect2, varscan2
- MFSD10 | c.675G>A p.T225= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs758203082, COSV53275372; called by muse, mutect2, varscan2
- MRGPRX4 | c.954C>T p.S318= | Silent (SNP) | VAF 21/133 reads (16%) | catalogued as rs1282005037, COSV58591978; called by muse, mutect2, varscan2
- MTFR1 | c.717A>G p.L239= | Silent (SNP) | VAF 22/117 reads (19%) | catalogued as rs745400965, COSV50953527; called by muse, mutect2, varscan2
- MYH7 | c.210C>T p.T70= | Silent (SNP) | VAF 43/253 reads (17%) | catalogued as rs774429242, COSV100806269, COSV62519754; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYORG | c.213G>A p.A71= | Silent (SNP) | VAF 13/99 reads (13%) | catalogued as rs1221710670, COSV52627713; called by muse, mutect2, varscan2
- NCAPG2 | c.876C>T p.H292= | Silent (SNP) | VAF 53/158 reads (34%) | catalogued as rs925375163, COSV51987252; called by muse, mutect2, varscan2
- NRXN2 | c.1653C>T p.A551= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as rs374777953; ClinVar: likely benign; called by muse, mutect2, varscan2
- OAS3 | c.2937C>A p.A979= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as COSV57450016; called by muse, mutect2, varscan2
- OR2L2 | c.648C>A p.S216= | Silent (SNP) | VAF 26/552 reads (5%) | catalogued as COSV100823002; called by muse, mutect2
- PCDHA8 | c.1536G>A p.T512= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV65331912; called by muse, mutect2
- PCDHGB1 | c.1791C>T p.N597= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs1319194846, COSV54051120; called by muse, mutect2, varscan2
- PHKB | c.2418T>C p.H806= | Silent (SNP) | VAF 76/250 reads (30%) | catalogued as COSV54536584; called by muse, mutect2, varscan2
- PIK3CB | c.2865A>C p.R955= | Silent (SNP) | VAF 10/245 reads (4%) | catalogued as COSV100005580; called by muse, mutect2
- PLEKHA5 | c.3132C>A p.T1044= | Silent (SNP) | VAF 13/163 reads (8%) | catalogued as COSV100163959; called by muse, mutect2
- POLRMT | c.426G>A p.A142= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs139310135; called by mutect2, varscan2
- RABL2A | c.87C>T p.D29= | Silent (SNP) | VAF 20/158 reads (13%) | catalogued as rs1412393496; called by mutect2, varscan2
- RABL2B | c.87C>T p.D29= | Silent (SNP) | VAF 83/410 reads (20%) | catalogued as COSV61484061; called by muse, mutect2, varscan2
- RACK1 | c.774C>A p.I258= | Silent (SNP) | VAF 47/136 reads (35%) | catalogued as COSV59322880; called by muse, mutect2, varscan2
- RAP1GAP | c.864C>T p.I288= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as rs749949142, COSV51580079; called by muse, mutect2, varscan2
- RAPGEF4 | c.2028C>T p.C676= | Silent (SNP) | VAF 69/219 reads (32%) | catalogued as COSV51418624, COSV99911731; called by muse, mutect2, varscan2
- RBM12B | c.885T>C p.I295= | Silent (SNP) | VAF 5/102 reads (5%) | catalogued as COSV101197142; called by muse, mutect2
- RSKR | c.216C>T p.A72= | Silent (SNP) | VAF 43/132 reads (33%) | catalogued as COSV56384399; called by muse, mutect2, varscan2
- RTL9 | c.1734A>G p.P578= | Silent (SNP) | VAF 27/153 reads (18%) | catalogued as COSV71826609; called by muse, mutect2, varscan2
- RYR3 | c.1876C>A p.R626= | Silent (SNP) | VAF 94/306 reads (31%) | catalogued as COSV66780293, COSV66811073; called by muse, mutect2, varscan2
- SAMD12 | c.246C>A p.V82= | Silent (SNP) | VAF 38/203 reads (19%) | catalogued as COSV59058484; called by muse, mutect2, varscan2
- SCAF11 | c.1395T>C p.D465= | Silent (SNP) | VAF 28/226 reads (12%) | catalogued as rs1436678765, COSV65476118; called by muse, mutect2, varscan2
- SCUBE2 | c.366C>T p.D122= | Silent (SNP) | VAF 20/174 reads (11%) | catalogued as rs369076752; called by muse, mutect2, varscan2
- SIN3A | c.1623C>T p.G541= | Silent (SNP) | VAF 45/271 reads (17%) | catalogued as COSV64585469; called by muse, mutect2, varscan2
- SIPA1 | c.3084C>T p.L1028= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV58016333; called by muse, mutect2, varscan2
- SLC27A1 | c.846T>C p.A282= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV53101483; called by muse, mutect2, varscan2
- SLC38A10 | c.2739C>T p.L913= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs535691605, COSV66100421; called by muse, mutect2, varscan2
- SLC7A13 | c.1371A>G p.Q457= | Silent (SNP) | VAF 37/228 reads (16%) | catalogued as rs1356586582, COSV52538066; called by muse, mutect2, varscan2
- SMARCA4 | c.321G>C p.G107= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV100758477, COSV60786144; called by muse, mutect2, varscan2
- SOS2 | c.1002T>C p.R334= | Silent (SNP) | VAF 12/130 reads (9%) | catalogued as rs1332611541, COSV99365992; called by muse, mutect2
- SPHK2 | c.1719C>T p.S573= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV55342701; called by muse, mutect2, varscan2
- SSX2IP | c.1815T>C p.N605= | Silent (SNP) | VAF 57/330 reads (17%) | catalogued as COSV60554933; called by muse, mutect2, varscan2
- ST14 | c.184C>T p.L62= | Silent (SNP) | VAF 13/128 reads (10%) | catalogued as COSV99598709; called by muse, mutect2
- STAG2 | c.1437C>T p.Y479= | Silent (SNP) | VAF 17/382 reads (4%) | catalogued as COSV54356277, COSV99493317; called by muse, mutect2
- TBK1 | c.2127C>T p.H709= | Silent (SNP) | VAF 15/192 reads (8%) | catalogued as COSV100538149; called by muse, mutect2
- THADA | c.4674A>G p.S1558= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as rs1471000575, COSV57694874; called by muse, mutect2, varscan2
- TIAM2 | c.1065C>A p.S355= | Silent (SNP) | VAF 28/96 reads (29%) | catalogued as COSV59705679; called by muse, mutect2, varscan2
- TICAM1 | c.2109G>A p.A703= | Silent (SNP) | VAF 5/69 reads (7%) | catalogued as rs1400942979, COSV104442031; called by muse, mutect2
- TMEM51 | c.495G>A p.T165= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as rs748435182, COSV65691562; called by muse, mutect2, varscan2
- TMPRSS11E | c.27G>A p.R9= | Silent (SNP) | VAF 41/246 reads (17%) | catalogued as COSV100542346; called by muse, mutect2, varscan2
- TMPRSS5 | c.549A>G p.G183= | Silent (SNP) | VAF 48/223 reads (22%) | catalogued as COSV55426708; called by muse, mutect2, varscan2
- TRIM67 | c.2244C>T p.D748= | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as rs762247535, COSV64159856; called by muse, mutect2, varscan2
- TTC37 | c.999G>A p.L333= | Silent (SNP) | VAF 10/119 reads (8%) | catalogued as COSV100706600; called by muse, mutect2
- TUBA3E | c.856C>T p.L286= | Silent (SNP) | VAF 38/190 reads (20%) | catalogued as COSV56060074; called by muse, mutect2
- USH2A | c.9048C>T p.C3016= | Silent (SNP) | VAF 32/141 reads (23%) | catalogued as rs1057519208, COSV56361793; called by muse, mutect2, varscan2
- VAV1 | c.141T>C p.L47= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as COSV58392698; called by muse, mutect2, varscan2
- VILL | c.1425C>T p.G475= | Silent (SNP) | VAF 15/123 reads (12%) | catalogued as COSV99378758; called by muse, mutect2, varscan2
- WAPL | c.3345C>T p.H1115= | Silent (SNP) | VAF 10/128 reads (8%) | catalogued as COSV99556454; called by muse, mutect2
- WSCD1 | c.1419G>A p.S473= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs780761088, COSV58494238; called by muse, mutect2, varscan2
- XRN2 | c.1419G>A p.S473= | Silent (SNP) | VAF 55/152 reads (36%) | catalogued as rs535403975, COSV65872002; called by muse, mutect2, varscan2
- ZFYVE9 | c.1014T>C p.P338= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as COSV55101654; called by muse, mutect2, varscan2
- ZNF18 | c.1569G>A p.S523= | Silent (SNP) | VAF 52/305 reads (17%) | catalogued as rs372916550; called by muse, mutect2, varscan2
- ZNF286A | c.1452T>C p.H484= | Silent (SNP) | VAF 10/178 reads (6%) | catalogued as COSV101224764; called by muse, mutect2
- ZNF630 | c.1788G>A p.E596= | Silent (SNP) | VAF 102/287 reads (36%) | catalogued as rs373564392, COSV52098510; called by muse, mutect2, varscan2
- ZNF99 | c.2196C>T p.P732= | Silent (SNP) | VAF 4/54 reads (7%) | catalogued as COSV101233814; called by muse, mutect2
- ELMOD1 | c.-86+379G>A | Intron (SNP) | VAF 8/44 reads (18%) | catalogued as COSV99759967; called by muse, mutect2, varscan2
- MASP1 | c.1303+5063G>T | Intron (SNP) | VAF 8/125 reads (6%) | catalogued as COSV99962246; called by muse, mutect2
- SSPOP | n.10011dup | RNA (INS) | VAF 7/16 reads (44%) | called by mutect2, varscan2
- UBTFL2 | n.481C>T | RNA (SNP) | VAF 63/218 reads (29%) | called by muse, mutect2, varscan2
- USH1C | c.1284+6980A>G | Intron (SNP) | VAF 20/121 reads (17%) | catalogued as COSV50041439; called by muse, mutect2, varscan2
- Y_RNA | chr7:75511114 G>A | 3'Flank (SNP) | VAF 8/112 reads (7%) | catalogued as rs782477398; called by muse, mutect2
